Somatic mutation profile of tumor specimen MP2PRT-PAVEJH-TMP1-A (aliquot MP2PRT-PAVEJH-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVEJH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,169 days).
Specimen MP2PRT-PAVEJH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99d3cef7-1fbf-4fbf-b3c0-196d1b702268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEJH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEJH-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6940956-9f8e-4312-a8b8-2b0531510428

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AQP4 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.251); catalogued as rs772226682, COSV104431163; called by muse, mutect2, varscan2
- FAM53A | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 230/958 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs770489242; called by muse, mutect2, varscan2
- HCN1 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 140/285 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs142280884; called by muse, varscan2
- MFAP3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs774089662, COSV59456823; called by muse, mutect2, varscan2
- RBM38 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 247/531 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs762156310; called by muse, mutect2, varscan2
- THSD4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 240/444 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs776401272; called by muse, mutect2, varscan2
- TUBA3C | c.1301A>G p.E434G | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as COSV68028987; called by muse, mutect2, varscan2
- XDH | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC59 | c.366G>A p.P122= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs780594420; called by muse, mutect2, varscan2
- MMS22L | c.3519C>T p.Y1173= | Silent (SNP) | VAF 62/196 reads (32%) | called by muse, mutect2, varscan2
